CCDI case PBBTNG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/e2b56402-ba7b-462c-8b85-332fbf65b815

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Age at diagnosis: 10.2 years (3,720 days).

Biospecimens (3 samples)
- Sample 0DHBCW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHBCY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHBCZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
